Somatic mutation profile of tumor specimen TCGA-CD-8532-01A (aliquot TCGA-CD-8532-01A-11D-2340-08) from TCGA case TCGA-CD-8532, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 52.8 years (19,284 days).
Specimen TCGA-CD-8532-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c92b02fe-1c79-452b-b192-145e3f9dd885.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-8532-10A (Blood Derived Normal), aliquot TCGA-CD-8532-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1024b3e-61b7-4911-bd42-7531c5e85315

The open-access MAF lists 44 somatic variants for this specimen: 28 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 15, Frame Shift Ins 2, Nonsense Mutation 2, Splice Site 1, Splice Region 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA1 | c.4272C>T p.I1424= | Splice Region (SNP) | VAF 12/27 reads (44%) | catalogued as COSV66063966; called by muse, mutect2, varscan2
- ATF7 | c.1058A>G p.N353S (on ENST00000548446 / NM_001366555.2; = p.N342S on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1309875882, COSV60643129; called by muse, mutect2, varscan2
- ATP1A1 | c.297dup p.F100Vfs*17 | Frame Shift Ins (INS) | VAF 19/75 reads (25%) | catalogued as rs1360019202; called by mutect2, pindel, varscan2
- ATRN | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53526595, COSV53530456; called by muse, mutect2, varscan2
- AZI2 | c.616A>T p.S206C | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV55423701; called by muse, mutect2, varscan2
- C2orf78 | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs557579254, COSV68517227; called by muse, mutect2, varscan2
- C4orf33 | c.494+2T>G p.X165_splice | Splice Site (SNP) | VAF 7/28 reads (25%) | catalogued as COSV55415688; called by muse, mutect2, varscan2
- CLDN8 | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); catalogued as rs893943148, COSV54525776; called by muse, mutect2, varscan2
- CXCR2 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.119); catalogued as rs1014647889, COSV59279796; called by muse, mutect2, varscan2
- DLST | c.748A>G p.T250A | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as rs376668007; called by muse, mutect2, varscan2
- EHHADH | c.76A>G p.T26A | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV51629266; called by muse, mutect2, varscan2
- ETNK1 | c.365T>C p.I122T | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV56884928; called by muse, mutect2, varscan2
- EVC2 | c.3220C>G p.L1074V | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60391641; called by muse, mutect2, varscan2
- KCND2 | c.97C>G p.Q33E | Missense Mutation (SNP) | VAF 46/237 reads (19%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV58576467; called by muse, mutect2, varscan2
- PPP6R2 | c.2171C>T p.T724M (on ENST00000216061 / NM_001365836.1; = p.T697M on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs148549099; called by muse, mutect2
- ROBO2 | c.500G>A p.W167* | Nonsense Mutation (SNP) | VAF 18/111 reads (16%) | catalogued as COSV59905065; called by muse, mutect2, varscan2
- RP1 | c.6398T>C p.L2133P | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV55114701, COSV99608701; called by muse, mutect2
- SERPING1 | c.1292C>A p.T431K | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53542204; called by muse, mutect2, varscan2
- SLC8A2 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.998); catalogued as rs372858973; called by muse, varscan2
- STRN | c.2102C>T p.S701L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs750553167, COSV55747341; called by muse, mutect2, varscan2
- TTC29 | c.1141T>A p.F381I | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV57273943; called by muse, mutect2
- ZAN | c.2645C>T p.T882M | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as rs374960098; called by muse, mutect2, varscan2
- ZNF157 | c.931T>A p.F311I | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65658746; called by muse, mutect2, varscan2
- ZNF470 | c.1897C>T p.R633C | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs143160710; called by muse, mutect2, varscan2
- ZNF567 | c.907C>T p.H303Y (on ENST00000536254 / NM_001322913.1; = p.H272Y on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62444531, COSV62444916; called by muse, mutect2
- CIC | c.402_406del p.P135Rfs*7 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | called by mutect2, pindel, varscan2
- KDM5C | c.2276dup p.M759Ifs*4 | Frame Shift Ins (INS) | VAF 22/58 reads (38%) | called by mutect2, pindel, varscan2
- SMARCA2 | c.1003C>T p.Q335* | Nonsense Mutation (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- ADAD2 | c.792C>T p.T264= (on ENST00000315906 / NM_001145400.2; = p.T346= on NM_139174.4) | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs372344589; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2373G>A p.T791= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs773737016, COSV54444093, COSV99720159; called by muse, mutect2, varscan2
- APBB2 | c.1995C>T p.D665= (on ENST00000295974 / NM_001166050.2; = p.D666= on NM_004307.2) | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs760354590, COSV55950897; called by muse, mutect2, varscan2
- BRINP2 | c.906C>A p.T302= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV64176944, COSV64179208; called by muse, mutect2, varscan2
- CNOT4 | c.1143A>G p.V381= (on ENST00000315544 / NM_001190848.1; = p.V378= on NM_013316.4) | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as rs763977175, COSV59651459; called by muse, mutect2, varscan2
- DENND4A | c.2745A>G p.E915= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV71265605; called by muse, mutect2, varscan2
- GDF5 | c.1332G>A p.T444= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs529197082, COSV65499041; called by muse, mutect2, varscan2
- INTS1 | c.1704A>G p.E568= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV67177133; called by muse, mutect2, varscan2
- PSG3 | c.324G>A p.L108= | Silent (SNP) | VAF 102/460 reads (22%) | catalogued as COSV59503750; called by muse, mutect2, varscan2
- SLC35B1 | c.408C>T p.V136= (on ENST00000649906; = p.V99= on NM_005827.4) | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs766786550, COSV53602746; called by muse, mutect2, varscan2
- SOX14 | c.426G>T p.A142= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV60162671, COSV60162751; called by muse, mutect2, varscan2
- TENM4 | c.4515C>T p.L1505= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs372767827; called by mutect2, varscan2
- TFG | c.807T>C p.G269= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as COSV52533810; called by muse, mutect2, varscan2
- TMX1 | c.366C>T p.D122= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV63284823; called by muse, mutect2, varscan2
- TXK | c.21C>T p.N7= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV51914188; called by muse, mutect2, varscan2
- BIRC8 | n.1410C>T | RNA (SNP) | VAF 39/178 reads (22%) | catalogued as rs113838023, COSV70346684, COSV70346698; called by muse, mutect2, varscan2
